CPTAC case C3L-04265 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3dcde5fa-f597-4848-8992-5fbe17203fbd

Demographics
Sex at birth: female; Race: white; Year of birth: 1954; Vital status: Dead; Days to death: 456 days (1.2 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.3 years (23,490 days); Year of diagnosis: 2018; Days to last known disease status: 456 days (1.2 years); Progression or recurrence: yes; Days to recurrence: 246 days; Days to last follow up: 705 days (1.9 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Stem Cell Transplantation, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 359 days; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 705 days (1.9 years); Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 705 days (1.9 years); Progression or recurrence: Yes; Days to recurrence: 246 days; Karnofsky performance status: 10; ECOG performance status: 4.

Other clinical attributes
- Weight: 80 kg; Height: 165 cm; BMI: 29.38.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (5 samples)
- Samples C3L-04265-50, C3L-04265-51, C3L-04265-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-04265-54, C3L-04265-56 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 285 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
